Somatic mutation profile of tumor specimen TCGA-FB-AAPY-01A (aliquot TCGA-FB-AAPY-01A-11D-A40W-08) from TCGA case TCGA-FB-AAPY, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 71.4 years (26,085 days).
Specimen TCGA-FB-AAPY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2faf47e8-e1a3-4b8e-acb9-a3920b4c4163.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-AAPY-11A (Solid Tissue Normal), aliquot TCGA-FB-AAPY-11A-11D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c78a557f-3ef9-4551-a5ae-522198520eda

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 6, RNA 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K4 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 37/285 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62254615; called by muse, mutect2, varscan2
- SMAD4 | c.533C>A p.S178* | Nonsense Mutation (SNP) | VAF 73/431 reads (17%) | hotspot (GDC flag); catalogued as CM994756, COSV61686156, COSV61688610, COSV61689431; called by muse, mutect2, varscan2
- AFF2 | c.3913C>T p.R1305C | Missense Mutation (SNP) | VAF 126/530 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs782120451, COSV53987481; called by muse, mutect2, varscan2
- APCDD1 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 128/735 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV100789895; called by muse, mutect2, varscan2
- ATP10A | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 49/427 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs767762690, COSV63515971; called by muse, mutect2, varscan2
- CNOT3 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as rs767913658, COSV99651444; called by muse, mutect2
- CPXM2 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 68/687 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs372846460; called by muse, mutect2
- DCAF8 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 130/993 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV100470118; called by muse, mutect2, varscan2
- ESR2 | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 92/609 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99962773; called by muse, mutect2, varscan2
- GJC1 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 85/626 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as rs753057256, COSV57911321; called by muse, mutect2, varscan2
- KIF1A | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397376358, COSV57506858; called by muse, mutect2, varscan2
- KRTAP19-3 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 150/1208 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs371263018; called by muse, mutect2, varscan2
- KRTAP4-2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 84/558 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.515); catalogued as rs754307555, COSV66658212; called by muse, mutect2, varscan2
- LRP1 | c.6433A>G p.I2145V | Missense Mutation (SNP) | VAF 46/539 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.891); catalogued as COSV99674264; called by muse, mutect2
- MDM1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759413758, COSV100291578; called by muse, mutect2, varscan2
- NPFFR1 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745639559, COSV99524646; called by muse, mutect2, varscan2
- NRXN2 | c.4523C>T p.T1508M | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1298089019, COSV99632381; called by muse, mutect2
- OR4D5 | c.318C>A p.F106L | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV100189710; called by muse, mutect2, varscan2
- OR8B12 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as rs1315333670, COSV60911683; called by muse, mutect2, varscan2
- PARP12 | c.599A>T p.D200V | Missense Mutation (SNP) | VAF 73/577 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV99693784; called by muse, mutect2, varscan2
- PCDHA2 | c.1793A>G p.D598G | Missense Mutation (SNP) | VAF 61/484 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as COSV65366350; called by muse, mutect2, varscan2
- ROCK1 | c.2498G>A p.R833K | Missense Mutation (SNP) | VAF 54/434 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV101296221, COSV101296510; called by muse, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 32/285 reads (11%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- ZNF114 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 248/958 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as COSV100251894; called by muse, mutect2, varscan2
- TRDJ3 | c.28T>A p.F10I | Missense Mutation (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2
- ADSS2 | c.1251G>A p.A417= | Silent (SNP) | VAF 65/416 reads (16%) | catalogued as rs191651118, COSV100836789; called by muse, mutect2, varscan2
- ATP10A | c.2349C>T p.D783= | Silent (SNP) | VAF 48/382 reads (13%) | catalogued as rs762984844, COSV100790802; called by muse, mutect2, varscan2
- C1orf127 | c.2274G>A p.T758= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs753501464, COSV100983389; called by muse, mutect2
- CCDC102A | c.648G>A p.E216= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99264771; called by muse, mutect2
- NTM | c.624C>T p.A208= | Silent (SNP) | VAF 28/192 reads (15%) | catalogued as rs768642700, COSV100867239, COSV100867633; called by muse, mutect2, varscan2
- PARD3 | c.1647C>T p.D549= | Silent (SNP) | VAF 146/998 reads (15%) | catalogued as rs767494732, COSV100400148; called by muse, mutect2, varscan2
- C11orf40 | n.258T>A | RNA (SNP) | VAF 30/447 reads (7%) | catalogued as rs143067877, COSV100296371; called by muse, mutect2
